Surgical pathology report (de-identified scan), TCGA case TCGA-78-7163, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Prince Charles Hospital, specimen TCGA-78-7163-01A (Primary Tumor).

RIGHT LOWER LOBECTOMY

Macroscopy:

Specimen consists of lung tissue 140 x 100 x 20 mm containing tumour 40 mm in diameter which abuts the pleura. The tumour has a mucoid grey cut surface.

Microscopy:

Sections show a well differentiated mucinous adenocarcinoma growing in a lepidic pattern. There is focal central necrosis. The excision lines are clear of malignancy. Ten lymph nodes from the 11R group are free of malignancy.

SUMMARY:

Right lower lobectomy: well differentiated adenocarcinoma.

/Over

COMMENT:

The tumour is consistent with a lung primary but a metastatic tumour could also produce this appearance.

Pathologist: DR [REDACTED]

Report validated by pathologist/registrar

Source: NCI Genomic Data Commons file 4f20c0cf-9ed9-461e-a356-233693b74121 (TCGA-78-7163.40948CA8-3075-47EF-A679-94EA5DC29A08.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).